CCDI case PBCNPR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/92ca08e2-58ee-4449-8ee0-b4b916021d26

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 6.5 years (2,361 days).

Biospecimens (3 samples)
- Sample 0DW41Q: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW422: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW42E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
